Surgical pathology report (de-identified scan), TCGA case TCGA-85-A4JB, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-A4JB-01A (Primary Tumor).

[page 1 of 2]
Gross Description: Right upper lobe with free lobar bronchus; on section, a central tumoral structure of 10/12/8 cm in diameter, which infiltrates the visceral pleura; the tumor is well-limited, white, with necrosis and central ulceration.

Microscopic Description: TUMOR FRAGMENT WITH PLEURA:

Bronchopulmonary neoplasm of epidermoid carcinoma type, G2, with a tendency to keratinization, formed of solid beaches of large, pleomorphic cells, with frequent nuclear atypias and atypical mitoses, with hotbeds of necrosis; important, fibrocollagenous stromal reaction.

BRONCHIAL RECUPA:

Fragments of bronchial wall without tumoral aspect.

TUMOR FRAGMENT: A fragment of 1.2/1/0.8 cm.

Tumoral fragment of epidermoid carcinoma with keratinization.

HILAR LYMPH NODE: No metastases.

PARIETAL PLEURA:

Fragments of pleura with collagenization and stasis in the juxta-pleural capillary vessels, without tumoral infiltration.

LYMPH NODE STATION II: No metastases.

RIB VI - PERIOSTEUM:

12 cm long rib fragment, without tumoral aspect.

Fragment of osseous tissue, without tumoral infiltration; the fibro-muscular-adipose juxta-coastal connective tissue with tumoral infiltration of the epidermoid carcinoma.

Diagnosis Details:

Comments:

Formatted Path Reports: LUNG TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor site: Lung

Tumor size: 10 x 12 x 8 cm

1CS-0-3

carcinoma, squamous cell, nos
8070/3

Site: lung, upper lobe
C34.1

W
10/2/12

[page 2 of 2]
Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Visceral pleura

Other tumor nodules: Not specified

Lymph nodes: 0/2 positive for metastasis (St.10,2 0/2)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Right- upper

lu
3/12

Source: NCI Genomic Data Commons file 6d7ec2cb-5cf1-46b5-b3ae-adb372d793f7 (TCGA-85-A4JB.36440AEA-EB5D-42B9-B6BE-B395C54E0407.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).